Surgical pathology report (de-identified scan), TCGA case TCGA-39-5034, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5034-01A (Primary Tumor).

[page 1 of 7]
Clinical Diagnosis & History:

Pt. had work up for MVA with right upper lobe mass, FNA () positive NSCLC, favor adenocarcinoma. CT chest (); right upper lobe mass and right lower lobe nodule.

Specimens Submitted:

- 1: LYMPH NODES; RIGHT LEVEL FOUR MEDIASTINAL; EXCISION
- 2: BONE, PORTION OF SIXTH RIB; EXCISION
- 3: BONE, PORTION OF 3RD RIB; EXCISION
- 4: BONE, PORTION OF 2ND RIB; EXCISION
- 5: BONE, FINAL POSTERIOR MARGIN OF 3RD RIB; EXCISION
- 6: BONE, FINAL POSTERIOR MARGIN OF 2ND RIB; EXCISION
- 7: BONE, FINAL ANTERIOR MARGIN OF 2ND RIB; EXCISION
- 8: BONE, FINAL ANTERIOR MARGIN OF 3RD RIB; EXCISION
- 9: LYMPH NODE, RIGHT LEVEL TWELVE MEDIASTINAL; EXCISION
- 10: LYMPH NODE, RIGHT LEVEL TEN MEDIASTINAL; EXCISION
- 11: LYMPH NODE, RIGHT LEVEL 11 INTERLOBAR; EXCISION
- 12: LUNG, RIGHT UPPER LOBE AND PORTIONS OF RIGHT 2ND 3RD RIBS; LOBECTOMY AND CHEST RESECTION

DIAGNOSIS:

1. LYMPH NODES; RIGHT LEVEL FOUR MEDIASTINAL; EXCISION:
- ELEVEN BENIGN LYMPH NODES (0/11)
2. BONE, PORTION OF SIXTH RIB; EXCISION:
- BENIGN BONE AND SKELETAL MUSCLE.
- NO TUMOR SEEN.
3. BONE, PORTION OF 3RD RIB; EXCISION:
- BENIGN BONE AND SKELETAL MUSCLE.
- NO TUMOR SEEN.
4. BONE, PORTION OF 2ND RIB; EXCISION:
- BENIGN BONE, FIBROADIPOSE TISSUE, AND SKELETAL MUSCLE.
- NO TUMOR SEEN.
5. BONE, FINAL POSTERIOR MARGIN OF 3RD RIB; EXCISION:
- BENIGN BONE, FIBROADIPOSE TISSUE, AND SKELETAL MUSCLE.
- NO TUMOR SEEN.

** Continued on next page **

[page 2 of 7]
6. BONE, FINAL POSTERIOR MARGIN OF 2ND RIB; EXCISION:
- BENIGN BONE, FIBROADIPOSE TISSUE, AND SKELETAL MUSCLE.
- NO TUMOR SEEN.
7. BONE, FINAL ANTERIOR MARGIN OF 2ND RIB; EXCISION:
- BENIGN BONE, FIBROADIPOSE TISSUE, AND SKELETAL MUSCLE.
- NO TUMOR SEEN.
8. BONE, FINAL ANTERIOR MARGIN OF 3RD RIB; EXCISION:
- BENIGN BONE, FIBROADIPOSE TISSUE, AND SKELETAL MUSCLE.
- NO TUMOR SEEN.
9. LYMPH NODE, RIGHT LEVEL TWELVE MEDIASTINAL; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
10. LYMPH NODE, RIGHT LEVEL TEN MEDIASTINAL; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
11. LYMPH NODE, RIGHT LEVEL 11 INTERLOBAR; EXCISION:
- THREE BENIGN LYMPH NODE (0/3).
12. LUNG, RIGHT UPPER LOBE AND PORTIONS OF RIGHT 2ND 3RD RIBS;
LOBECTOMY AND CHEST RESECTION:
- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.
- THE TUMOR MEASURES 3.2 CM IN GREATEST DIMENSION.
- THE TUMOR INVOLVES THE CHEST WALL INTOSKELETAL MUSCLE.
- VASCULAR INVASION IS PRESENT.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE VASCULAR MARGIN IS FREE OF TUMOR.
- THE NON-NEOPLASTIC LUNG SHOWS RESPIRATORY BRONCHIOLITIS AND FOCAL EMPHYSEMATOUS CHANGES.
- TWO BENIGN LYMPH NODES (0/2).
- BENIGN BONE AND SKELETAL MUSCLE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

1). The specimen is received fresh for frozen section consultation, labeled "Right level 4 mediastinal lymph node". It consists of a fragment of yellow black soft tissue measuring 3.0 x 1.8 x 1.3 cm. There are multiple lymph nodes identified and submitted entirely for frozen section consultation.

Summary of sections:
FSCA-frozen section control A

** Continued on next page **

[page 3 of 7]
2). The specimen is received in formalin, labeled "Portion of right sixth rib". It consists of a 3 x 2 x 1.2 cm fragmented segment of rib. There is no discrete abnormality identified. Representative sections are submitted after decalcification.

Summary of sections:
U-undesignated

3). The specimen is received in formalin, labeled "Portion of right third rib". It consists of three pieces of brown tan bony tissue ranging from 1.5 x 0.8 x 0.4 cm up to 2.0 x 1.4 x 0.5 cm. Representative sections are submitted after decalcification.

Summary of sections:
U-undesignated

4). The specimen is received in formalin, labeled "Portion of right second rib". It consists of three pieces of brown tan bony tissue measuring 5 x 3 x 0.7 cm in aggregate. There are no discrete abnormalities identified. Representative sections are submitted as decalcification.

Summary of sections:
U-undesignated

5). The specimen is received in formalin labeled "Right final posterior margin of third rib". It consists of a segment of rib measuring 4 cm in length and 1.4 cm in diameter. There is attached skeletal muscle measuring 5.5 x 3 x 1.5 cm. The resected margins of the rib are inked black. On bivalving the rib it shows unremarkable trabeculated appearance. Cut section of the skeletal muscle it is grossly unremarkable. Representative sections are submitted after decalcification.

Summary of sections:
M-bone with resected margins
U-skeletal muscle

6). The specimen is received in formalin, labeled "Final right posterior margin of second rib". It consists of a fragmented pieces of brown-tan bony tissue measuring 2.5 x 2 x 1.2 cm. The specimen is sectioned and submitted entirely after decalcification.

Summary of sections:
U-undesignated

** Continued on next page **

[page 4 of 7]
7). The specimen is received in formalin, labeled "Final right anterior margin of second rib". It consists of a 1.4 x 0.6 x 0.3 cm piece of brown-tan bone which is entirely submitted after decalcification.

Summary of sections:
U-undesignated

8). The specimen is received in formalin, labeled "Final right anterior margin of third rib". It consists of two fragmented pieces of brown-tan bony tissue measuring 2.2 x 2 x 0.6 cm in aggregate. Both are sectioned and submitted entirely.

Summary of sections:
U-undesignated

9). The specimen is received in formalin, labeled "Right level 12 mediastinal lymph node". It consists of a single anthracotic lymph node measuring 1.5 x 1.2 x 0.9 cm, which is bisected and submitted entirely.

Summary of sections:
U-undesignated

10). The specimen is received in formalin, labeled "Right level 10 mediastinal lymph node" and consists of a single anthracotic lymph node measuring 0.6 x 0.5 x 0.2 cm. The lymph node is entirely submitted.

Summary of sections:
U-undesignated

11). The specimen is received in formalin labeled "Right level 11 interlobar lymph node". It consists of multiple lymph nodes measuring 1.0 x 0.8 x 0.4 cm in aggregate. The lymph nodes are entirely submitted.

Summary of sections:
U-undesignated

12). The specimen is received in fresh state, labeled "right upper lobe lung with portions of second and third rib" and consists of a right upper lung lobe measuring 16 x 14 x 4.6 cm and laterally attached chest wall measuring 6.5 x 5.5 x 1.2 cm containing a segment of the second rib (4.6 cm in length 1.2 cm in diameter) and a segment of the third rib (6 cm in length

** Continued on next page **

[page 5 of 7]
----- Page 5 of 7

1.2 cm in diameter). A 15 cm staple line is identified on the medial aspect. Chest wall resection margin is inked. Sectioning reveals a 3.2 x 3.2 x 1.5 cm well-circumscribed tan firm mass at the periphery in the lateral aspect of the specimen at 4.3 cm from the bronchial margin. The tumor firmly adhered to the attached chest wall, and invasion is strongly suspected. Rib margins are submitted as separate parts. Multiple anthracotic peribronchial lymph nodes are identified. Background lung parenchyma shows diffuse severe emphysematous changes. TPS is previously taken. Bone is decalcified. The specimen is photographed.

Summary of sections:

BM -- bronchial margin
VM -- vascular margin
SL -- staple line
LN -- lymph node
T -- tumor
TCW -- tumor and chest wall (second rib is included)
2R -- additional section of second rib
3R -- third rib
RC -- background lung parenchyma close to the tumor (less than 3 cm)
RA -- background lung parenchyma away from the tumor (more than 3 cm)

Summary of Sections:

Part 1: LYMPH NODES; RIGHT LEVEL FOUR MEDIASTINAL; EXCISION

Block	Sect.	Site	PCs
1		fsca	1
1		fsch	1

Part 2: BONE, PORTION OF SIXTH RIB; EXCISION

Block	Sect.	Site	PCs
1		u	1

Part 3: BONE, PORTION OF 3RD RIB; EXCISION

Block	Sect.	Site	PCs
1		u	1

Part 4: BONE, PORTION OF 2ND RIB; EXCISION

Block	Sect.	Site	PCs
1		u	1

Part 5: BONE, FINAL POSTERIOR MARGIN OF 3RD RIB; EXCISION

Block	Sect.	Site	PCs
2		m	2
1		u	1

** Continued on next page **

[page 6 of 7]
Part 6: BONE, FINAL POSTERIOR MARGIN OF 2ND RIB; EXCISION

Block	Sect.	Site	PCs
3	u		3

Part 7: BONE, FINAL ANTERIOR MARGIN OF 2ND RIB; EXCISION

Block	Sect.	Site	PCs
1	u		1

Part 8: BONE, FINAL ANTERIOR MARGIN OF 3RD RIB; EXCISION

Block	Sect.	Site	PCs
2	u		2

Part 9: LYMPH NODE, RIGHT LEVEL TWELVE MEDIASTINAL; EXCISION

Block	Sect.	Site	PCs
1	u		1

Part 10: LYMPH NODE, RIGHT LEVEL TEN MEDIASTINAL; EXCISION

Block	Sect.	Site	PCs
1	u		1

Part 11: LYMPH NODE, RIGHT LEVEL 11 INTERLOBAR; EXCISION

Block	Sect.	Site	PCs
1	u		1

Part 12: LUNG, RIGHT UPPER LOBE AND PORTIONS OF RIGHT 2ND 3RD RIBS; LOBECTOMY AND CHEST RESECTION

Block	Sect.	Site	PCs
1		2r	1
1		3r	1
1		hm	1
1		ln	1
2		ra	2
2		rc	2
9		sl	9
3		t	3
3		tcw	3
1		vm	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]
PERMANENT DIAGNOSIS: SAME

** Continued on next page **

[page 7 of 7]
**** End of Report ****

Source: NCI Genomic Data Commons file 588dc007-f242-48d7-ac12-ae551d06d276 (TCGA-39-5034.8D0C1256-1E5C-4DB3-961D-15A4E1329224.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).